Gene-level copy-number profile of specimen HCM-CSHL-1270-C18-85N from HCMI case HCM-CSHL-1270-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GX; Age at diagnosis: 61.6 years (22,485 days).
Specimen HCM-CSHL-1270-C18-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c7065db-0a39-43d4-bedf-a20f2355d2e5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1270-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/46b75ea6-3efb-4707-b037-605a47809e6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 5,503; copy number 2: 41,537; copy number 3: 7,204; copy number 4: 3,998; copy number 5: 102; copy number 6: 5; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,132,350–189,133,292, 1 gene: GAPDHP75.
- chr1:190,480,379–190,494,297, 1 gene (within-gene range 0–3): AL391645.1.
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:90,121,786–90,160,335, 2 genes (within-gene range 0–1): IGKV2D-14, IGKV1D-12.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr4:130,881,027–130,885,641, 1 gene: AC093831.1.
- chr5:29,600,676–29,796,268, 2 genes: UBL5P1, AC108082.1.
- chr9:65,189,995–65,230,861, 3 genes: BMS1P12, AL512605.1, AL512605.2.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.
- chr21:13,095,305–13,113,790, 1 gene: ZNF355P.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 110 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:86,214,237–86,214,576, 1 gene, copy number 6: NDUFA5P9.
- chr7:63,011,463–63,011,569, 1 gene, copy number 6: RNU6-417P.
- chr8:43,493,937–43,494,762, 1 gene, copy number 7: AC134698.4.
- chr8:43,672,823–43,674,591, 2 genes, copy number 7: AC139365.2, AC139365.1.
- chr8:117,265,272–117,318,701, 2 genes, copy number 6: AC084114.1, AP002848.1.
- chr8:118,923,557–119,108,455, 4 genes, copy number 5 (within-gene range 4–5): TNFRSF11B, RNU6-12P, AC107953.1, COLEC10.
- chr8:122,414,332–122,428,551, 1 gene, copy number 6: SMILR.
- chr8:127,079,874–127,092,600, 2 genes, copy number 5: PRNCR1, AC020688.1.
- chr13:20,403,666–24,597,676, 95 genes, copy number 5 (broad region; genes not listed).
- chr13:79,804,418–79,805,685, 1 gene, copy number 5: LINC01038.

Autosomal genes at a single copy (total copy number 1): 5,503. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
